TARGET case TARGET-10-PAPDCR — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/4bf8f889-f8a0-4db2-91d4-8ec621a8c621

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Biospecimens (1 sample)
- Sample TARGET-10-PAPDCR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 3681
- WBC at Diagnosis: 56.4
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Positive
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 15: 4
- BMA Blasts Day 29: 0
- Karyotype: 55,XY,+X,+Y,+4,+6,+10,+14,+18,+21,+21[3]/46,XY[6]
- Down Syndrome: No
- DNA Index: 1.205
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: Trisomy of both chromosomes 4 and 10
